Somatic mutation profile of tumor specimen TCGA-B0-5115-01A (aliquot TCGA-B0-5115-01A-01D-1421-08) from TCGA case TCGA-B0-5115, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.6 years (15,935 days).
Specimen TCGA-B0-5115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 821533f8-c5a6-4380-a22c-654c885ccb9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5115-11A (Solid Tissue Normal), aliquot TCGA-B0-5115-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cff24700-7a05-4bfe-bcf3-3d9c5f278df2

The open-access MAF lists 60 somatic variants for this specimen: 52 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Nonsense Mutation 8, Silent 7, Frame Shift Del 6, Splice Site 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 35/188 reads (19%) | catalogued as rs1253211384, COSV63971413, COSV63977125; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 28/130 reads (22%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- ALPK1 | c.3443T>C p.V1148A | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV51589222; called by muse, mutect2, varscan2
- ARHGAP45 | c.1048T>A p.F350I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV57434539; called by muse, mutect2
- ARHGEF5 | c.4720G>T p.V1574F | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV50214780; called by muse, mutect2, varscan2
- CCDC68 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV61604417; called by muse, mutect2, varscan2
- DAXX | c.2045C>G p.S682C | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377663648, COSV56471558, COSV56472356; called by muse, mutect2, varscan2
- DPP10 | c.1795T>A p.F599I | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV59707582; called by muse, mutect2
- DSCAML1 | c.2383T>A p.Y795N (on ENST00000321322; = p.Y735N on NM_020693.4) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV58398146; called by muse, mutect2, varscan2
- DSCAML1 | c.2382G>C p.Q794H (on ENST00000321322; = p.Q734H on NM_020693.4) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV58398158; called by muse, mutect2, varscan2
- ENKD1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); catalogued as COSV54669303; called by muse, mutect2, varscan2
- FKBPL | c.479T>G p.I160R | Missense Mutation (SNP) | VAF 145/481 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV64322741; called by muse, mutect2, varscan2
- GBA2 | c.1851del p.W617* | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as COSV62306919; called by mutect2, pindel, varscan2
- GLG1 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 142/460 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV52671571; called by muse, mutect2, varscan2
- ICE1 | c.4741A>T p.S1581C | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as COSV56829322; called by muse, mutect2, varscan2
- IQCE | c.1865+2T>A p.X622_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV58080489; called by muse, mutect2, varscan2
- ITGA2 | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56864200; called by muse, mutect2, varscan2
- JAKMIP2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV54610947; called by muse, mutect2, varscan2
- LRP2 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs771153702, COSV55565527; called by muse, mutect2, varscan2
- MACF1 | c.4235G>A p.R1412H | Missense Mutation (SNP) | VAF 68/242 reads (28%) | catalogued as rs148253091, COSV58390870; called by muse, mutect2, varscan2
- MED7 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as COSV53850458; called by muse, mutect2, varscan2
- MICB | c.968T>A p.I323N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV52857299; called by muse, mutect2, varscan2
- PBRM1 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 39/93 reads (42%) | catalogued as COSV56280985, COSV56311253; called by muse, mutect2, varscan2
- PGC | c.221T>G p.F74C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63123477; called by muse, mutect2, varscan2
- PIMREG | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as rs151147808; called by muse, mutect2, varscan2
- PKD1 | c.3382T>A p.S1128T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV51921772; called by muse, mutect2
- PTPN1 | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV65408921; called by muse, mutect2, varscan2
- SART3 | c.2026C>T p.Q676* (on ENST00000228284; = p.Q658* on NM_014706.4) | Nonsense Mutation (SNP) | VAF 69/201 reads (34%) | catalogued as COSV57208018, COSV57209496; called by muse, mutect2, varscan2
- SIPA1L3 | c.2330G>C p.G777A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55909789; called by muse, mutect2, varscan2
- SOHLH2 | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV58522812; called by muse, mutect2, varscan2
- SORBS3 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53554116; called by muse, mutect2, varscan2
- SPINK5 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs777592836, COSV56259444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STXBP5L | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as rs1478208130, COSV56499540; called by muse, mutect2, varscan2
- TET2 | c.2269C>G p.L757V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54417070, COSV54424686; called by muse, mutect2, varscan2
- TMEFF2 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55832368, COSV55836960; called by muse, mutect2, varscan2
- TRIM36 | c.163A>T p.K55* | Nonsense Mutation (SNP) | VAF 45/222 reads (20%) | catalogued as COSV56691845; called by muse, mutect2, varscan2
- TRIM39 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV64956124; called by muse, mutect2, varscan2
- TTC14 | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV56013304; called by muse, mutect2, varscan2
- TTC14 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV56013349; called by muse, mutect2, varscan2
- VHL | c.370del p.T124Hfs*35 | Frame Shift Del (DEL) | VAF 83/262 reads (32%) | catalogued as CM138551, COSV56544507, COSV56549563; called by mutect2, pindel, varscan2
- VWF | c.4996C>G p.L1666V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV54628924; called by muse, mutect2, varscan2
- WBP11 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53764028; called by muse, mutect2, varscan2
- ZNF20 | c.1032T>A p.C344* | Nonsense Mutation (SNP) | VAF 43/161 reads (27%) | catalogued as COSV62000072; called by muse, mutect2, varscan2
- ZNF320 | c.655T>G p.C219G | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780919455, COSV67088626; called by muse, mutect2, varscan2
- ZNF432 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV55417810; called by muse, mutect2, varscan2
- C8orf37 | c.196_201del p.L66_I67del | In Frame Del (DEL) | VAF 31/153 reads (20%) | called by mutect2, pindel, varscan2
- CTNND2 | c.1436_1443del p.Q479Rfs*32 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | called by mutect2, pindel, varscan2
- GPRASP1 | c.2202dup p.T735Dfs*10 | Frame Shift Ins (INS) | VAF 69/130 reads (53%) | called by mutect2, pindel, varscan2
- OR5K2 | c.68del p.L23Rfs*14 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | called by mutect2, pindel*, varscan2
- RSBN1L | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 85/324 reads (26%) | called by mutect2, pindel, varscan2
- SMARCAD1 | c.1672+4del p.X558_splice | Splice Site (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2649_2650del p.K884Gfs*24 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | called by pindel, varscan2
- CD163 | c.2970G>C p.P990= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV63131655, COSV63135639; called by muse, mutect2, varscan2
- FZD10 | c.1659C>T p.S553= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57474858; called by muse, mutect2, varscan2
- LRRC36 | c.1318C>T p.L440= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV52081206; called by muse, mutect2, varscan2
- MXD4 | c.258C>T p.S86= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV61466808; called by muse, mutect2
- PEX26 | c.402T>G p.P134= | Silent (SNP) | VAF 36/430 reads (8%) | catalogued as COSV61605008, COSV61605030; called by muse, mutect2
- PRDM10 | c.465G>A p.T155= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as rs1375152056, COSV58799289; called by muse, mutect2, varscan2
- UBAP1 | c.750C>G p.S250= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV52659879, COSV52660510; called by muse, mutect2, varscan2
- RUSC1 | chr1:155320819 T>A | 5'Flank (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
